Gene-level copy-number profile of tumor specimen TCGA-FR-A44A-06A from TCGA case TCGA-FR-A44A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.7 years (13,398 days).
Specimen TCGA-FR-A44A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8ad26d9b-69be-46b5-a0ac-abbed06aec7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A44A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9de97592-a70a-47fb-80c9-c8d2270b7428

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 144; copy number 1: 18,556; copy number 2: 30,251; copy number 3: 10,386; copy number 4: 405; copy number 6: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A44A-06A-11D-A24Q-01): tumor purity 0.27, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,311,808, 8 genes: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:19,409,009–22,128,103, 74 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:22,086,407–22,505,167, 62 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:41,092,513–42,615,907, 75 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
